Gene-level copy-number profile of tumor specimen ALCH-B4Y4-TTP1-A from ALCHEMIST case ALCH-B4Y4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.7 years (26,905 days).
Specimen ALCH-B4Y4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5b985e10-f028-480c-9953-7153f51d903a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4Y4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/d4cacb10-a635-4633-974a-de5bf0c6bab9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,467; copy number 2: 54,430; copy number 3: 2,463; copy number 4: 34; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:117,542,445–117,549,546, 1 gene (within-gene range 0–2): EMX2.
- chr11:67,056,847–67,072,017, 1 gene: RHOD.
- chr17:81,976,807–82,031,151, 3 genes: ASPSCR1, CENPX, LRRC45.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:43,107,942–43,168,646, 1 gene, copy number 8 (within-gene range 2–8): AP001631.2.
- chr21:43,159,066–43,162,277, 1 gene, copy number 8: AP001631.1.

Autosomal genes at a single copy (total copy number 1): 1,466. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
